Somatic mutation profile of tumor specimen TCGA-BR-7722-01A (aliquot TCGA-BR-7722-01A-31D-2201-08) from TCGA case TCGA-BR-7722, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 62.2 years (22,701 days).
Specimen TCGA-BR-7722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ea9df4-0963-4b80-950c-6fbbf2581def.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7722-10A (Blood Derived Normal), aliquot TCGA-BR-7722-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4155b01c-fb2d-4deb-9420-8763bea15df6

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660556, CD064635, COSV61684006, COSV61691764, COSV61695842; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1L2 | c.2024T>C p.I675T | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs942899114, COSV51553649; called by muse, mutect2, varscan2
- ANO9 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs759531921, COSV60382604; called by muse, mutect2, varscan2
- ANTXR2 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55017511, COSV55019009; called by muse, mutect2, varscan2
- CACNA1B | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs775096777, COSV53116473, COSV99499754; called by muse, mutect2
- CUL5 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as rs1482602838, COSV63230033; called by muse, mutect2, varscan2
- DSCAML1 | c.6205G>A p.E2069K (on ENST00000321322; = p.E2009K on NM_020693.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.077); catalogued as rs747590806, COSV58383629; called by muse, mutect2, varscan2
- HCN4 | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56081821, COSV56087332; called by muse, mutect2, varscan2
- IFNA10 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 110/173 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as rs748350258, COSV53330608; called by muse, mutect2, varscan2
- ITPR1 | c.1033C>T p.R345W (on ENST00000354582; = p.R330W on NM_002222.7) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs369055445, COSV56970267; called by muse, mutect2, varscan2
- KIAA1109 | c.12685G>T p.V4229L | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52664433; called by muse, mutect2, varscan2
- KIF3A | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762622525, COSV66413366; called by muse, mutect2, varscan2
- LRP2 | c.10492C>T p.R3498C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.361); catalogued as rs749628580, COSV55543749; called by muse, mutect2, varscan2
- MDC1 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs751432651, COSV64523551; called by muse, mutect2, varscan2
- METTL15 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145080229; called by muse, mutect2, varscan2
- OR1L3 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 190/283 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59169301; called by muse, mutect2, varscan2
- PTPRH | c.2279T>C p.V760A | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV54743230; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1968T>G p.D656E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV62782559; called by muse, mutect2, varscan2
- RACK1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1390326067, COSV59317717; called by muse, mutect2
- RHOA | c.116T>G p.F39C | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69041851; called by muse, mutect2, varscan2
- SGSM3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs73420601, COSV50651328; called by muse, mutect2, varscan2
- SPG11 | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as COSV55991674; called by muse, mutect2, varscan2
- STK40 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs749198474, COSV100828688, COSV63734831; called by muse, mutect2, varscan2
- TMCO3 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as rs566169866, COSV64806926; called by muse, mutect2, varscan2
- TMEM132D | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1394998298, COSV67159014; called by muse, mutect2, varscan2
- YTHDF2 | c.1436A>G p.Y479C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65722841; called by muse, mutect2, varscan2
- YWHAH | c.397T>G p.Y133D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50708212; called by muse, mutect2, varscan2
- ZNF606 | c.2051A>G p.Q684R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV58705256; called by muse, mutect2
- ARID1A | c.3996dup p.Q1333Afs*5 | Frame Shift Ins (INS) | VAF 28/115 reads (24%) | called by pindel, varscan2
- ITGAV | c.2785del p.V929* | Frame Shift Del (DEL) | VAF 77/147 reads (52%) | called by mutect2, pindel, varscan2
- ADAM28 | c.2028G>A p.A676= | Silent (SNP) | VAF 56/202 reads (28%) | catalogued as rs778089939, COSV56098396; called by muse, mutect2, varscan2
- CACNA1E | c.3906C>T p.I1302= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV62384362; called by muse, mutect2, varscan2
- CHRNA3 | c.459C>T p.A153= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs202207061; ClinVar: likely benign; called by muse, mutect2, varscan2
- CIAO3 | c.1050G>A p.Q350= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs953992383, COSV52401008; called by muse, mutect2, varscan2
- IGHV3-48 | c.111G>T p.L37= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs782136971; called by muse, varscan2
- KCNG1 | c.45G>A p.A15= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs762916287, COSV65368214; called by muse, mutect2, varscan2
- MRPL41 | c.264C>T p.A88= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV52995144; called by muse, mutect2, varscan2
- OR6Y1 | c.312T>A p.T104= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV56928444; called by muse, mutect2, varscan2
- P2RY14 | c.147C>T p.Y49= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as rs763872146, COSV56370752; called by muse, mutect2, varscan2
- PON1 | c.931C>T p.L311= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as rs754968907, COSV55930912; called by muse, mutect2, varscan2
- RYR1 | c.10557C>G p.P3519= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV62091132; called by muse, mutect2, varscan2
- TMEM132D | c.91C>A p.R31= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV70596239, COSV70604577; called by muse, mutect2, varscan2
- ZNF607 | c.420A>G p.E140= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as rs1166239802, COSV67696358; called by muse, mutect2, varscan2
- RCC1 | c.73+613C>T | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
